Surgical pathology report (de-identified scan), TCGA case TCGA-ZG-A9L4, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University Medical Center Hamburg-Eppendorf, specimen TCGA-ZG-A9L4-01A (Primary Tumor).

[page 1 of 3]
Histopathological Report

Date of cancer sample procurement:

Date of pathology report:

Patient ID:

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
9/1/23/14

Gross description:

1. (Prostate gland): Prostate gland: Weight: 50 g, Volume: 45 ml, Size: 4.5 x 5.5 x 3.7 cm. Adherent seminal vesicles and deferent duct: right side: 2.8 cm, left side: 3.5 cm. The surface is marked with green ink on the right side, blue ink on the left side. On the left recto-lateral surface a 3.5 x 3 cm measuring tissue defect marked with yellow ink. Apical peri-urethral a funnel shaped 1.5 x 1 cm tissue defect marked with red ink. Total of the cross sections: 2 cm.
2. (Lymph nodes, right side): 6.8 x 3.5 x 1 cm measuring adipose tissue containing 2 nodes measuring up to 0.6 cm.
3. (Lymph nodes, left side): 4 x 2.1 x 1 cm measuring adipose tissue containing without palpable nodes.

Microscopy:

1. Apex right and left: Right 4 tissue blocks, left 5 tissue blocks (total 9 tissue blocks). 4 cross sections: Right 24 tissue blocks, left 21 tissue blocks (total 45 tissue blocks). Basis right and left: Right 9 tissue blocks, left 9 tissue blocks (total 18 tissue blocks). Seminal vesicles right and left: Right 3 tissue blocks, left 3 tissue blocks (total 6 tissue blocks). Deferent ducts right and left: Right 1 tissue block, left 1 tissue block (total 2 tissue blocks).
2. Frozen lymph nodes right: 4 tissue blocks.
3. Frozen lymph nodes left: 4 tissue blocks.

Diagnosis:

1. (Prostate gland): Poorly differentiated prostatic adenocarcinoma, Gleason 5+4=9, (Gleason 5: 50%, Gleason 4: 35%, Gleason 3: 15%). Tumor involves both lobes with the main focus on the right side rectolateral. Maximum tumor diameter: 44 mm. Perineural invasion. Positive surgical margin in 3 tissue blocks, apikal periurethral right side (contact length 2 mm; Gleason 4), apical left (contact length 0.2 mm; Gleason 3), left base (contact length 0.8 mm; Gleason 3).

Remaining prostatic tissue with small foci of prostatic intraepithelial neoplasia (high grade PIN) and signs of myoglandular hyperplasia of the prostate. Urothelium of the prostatic urethra without dysplasia. Tumor infiltration into both seminal vesicles. Tumor free resection margin of the deferent ducts.

2. (Lymph nodes, right side): Five tumor-free lymph nodes (0/5).
3. (Lymph nodes, left side): Five tumor-free lymph nodes (0/5).

[page 2 of 3]
Tumor classification

(in consideration of the intraoperative frozen-section, parallel report and immunohistochemical analyses):

pT3b, Gleason 5+4=9 (Gleason 5: 50%, Gleason 4: 35%, Gleason 3: 15%), maximum tumor diameter: 44 mm, tumor volume approx. 28.2 ml (Gleason 5: 14.1 ml, Gleason 4: 9.8 ml, Gleason 3: 4.3 ml), pN0 (0/10), L0, V0, R1

Comments:

In the preceding intraoperative frozen section prostatic adenocarcinoma was found on the left side with negative surgical margin.

The parallel transmittal „secondary resection sphincter“ revealed large adenocarcinoma infiltration (approximately 80% of biopsy area). Therefore, it has to be assumed that the tumor was not entirely resected (R1).

Immunohistochemical analyses (AE1/AE3) on four lymph nodes (2E, 3A+B) revealed no metastases. Immunohistochemical analyses (D2-CD31) on tissue block L1D showed no lymphatic or venous invasion.

One macroscopic image for tumor mapping.

*See dx discrepancy form for
Gleason 5+3.*

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

1/7/07

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____
Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Gleason 5+4	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Gleason 5+3	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Frozen sample tissue block submitted to TCGA has a different Gleason score than the frozen tissue block that was used for diagnosis.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature Date

Source: NCI Genomic Data Commons file 2d30adec-49c2-4032-b86e-bf2f656c955b (TCGA-ZG-A9L4.BC344956-732B-4A0A-9493-299442B05CD1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).